Gene-level copy-number profile of tumor specimen MP2PRT-PAVPRT-TMP1-A from MP2PRT case MP2PRT-PAVPRT, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.6 years (1,677 days).
Specimen MP2PRT-PAVPRT-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 4e62f971-8856-4f0f-84ff-4e9121a9ad84.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator MP2PRT-PAVPRT-NB1-A (blood derived cancer - peripheral blood, post-treatment); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,229 have no estimate.
https://portal.gdc.cancer.gov/files/e068f1e8-c003-4fe3-af7e-94e27c88b013

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 245; copy number 1: 777; copy number 2: 56,649; copy number 3: 723.

Homozygous deletions (total copy number 0; autosomes only): 245 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:88,811,186–89,310,144, 49 genes (within-gene range 0–2): MALLP2, AC244205.1, MIR4436A, IGKC, IGKJ5, IGKJ4, IGKJ3, IGKJ2, IGKJ1, IGKV4-1, IGKV5-2, IGKV7-3, PGBD4P5, IGKV2-4, IGKV1-5, IGKV1-6, IGKV3-7, IGKV1-8, IGKV1-9, IGKV2-10, IGKV3-11, IGKV1-12, IGKV1-13, IGKV2-14, IGKV3-15, IGKV1-16, IGKV1-17, IGKV2-18, IGKV2-19, IGKV3-20, IGKV6-21, IGKV1-22, IGKV2-23, IGKV2-24, IGKV3-25, IGKV2-26, AC244255.1, IGKV1-27, IGKV2-28, IGKV2-29, IGKV2-30, IGKV3-31, IGKV1-32, IGKV1-33, IGKV3-34, IGKV1-35, IGKV2-36, IGKV1-37, IGKV2-38.
- chr7:38,239,580–38,340,998, 16 genes (within-gene range 0–2): TRGC2, TRGJ2, TRGJP2, TRGC1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9, TRGVA, AC006033.2, TRGV8, TRGV7, TRGV6.
- chr7:38,345,030–38,350,022, 2 genes (within-gene range 0–2): TRGV5P, TRGV5.
- chr14:22,438,547–22,439,015, 2 genes (within-gene range 0–2): TRDD1, TRDD2.
- chr14:105,672,308–106,803,233, 175 genes (within-gene range 0–2) (broad region; genes not listed).
- chr15:88,252,730–88,271,066, 1 gene (within-gene range 0–1): NTRK3-AS1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 775. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
